Somatic mutation profile of tumor specimen TCGA-CD-A48C-01A (aliquot TCGA-CD-A48C-01A-11D-A24D-08) from TCGA case TCGA-CD-A48C, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 80.0 years (29,203 days).
Specimen TCGA-CD-A48C-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c418c8bf-9da0-4a40-a4e0-c0876eca4f71.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CD-A48C-10A (Blood Derived Normal), aliquot TCGA-CD-A48C-10A-01D-A24F-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f28286e6-e274-46aa-bb45-439e9ca53ce2

The open-access MAF lists 233 somatic variants for this specimen: 171 protein-altering or splice-affecting, 55 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 155, Silent 55, Nonsense Mutation 8, Splice Site 4, RNA 4, Frame Shift Del 3, Intron 3, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BNC2 | c.1723A>C p.S575R | Missense Mutation (SNP) | VAF 11/43 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.023); catalogued as rs1374823674, COSV66140362; called by muse, mutect2, varscan2
- ABCB4 | c.1931T>A p.L644Q | Missense Mutation (SNP) | VAF 7/98 reads (7%) | SIFT tolerated (0.57); PolyPhen benign (0.006); catalogued as rs775186230, COSV55935396; called by muse, mutect2
- ABCB4 | c.38G>A p.R13H | Missense Mutation (SNP) | VAF 14/174 reads (8%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs1037607543, COSV99709483; called by muse, mutect2
- ADAMTS19 | c.50T>A p.L17H | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.993); catalogued as COSV50747775; called by muse, mutect2, varscan2
- ADAMTS19 | c.2128A>C p.T710P | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT tolerated (0.72); PolyPhen benign (0.007); catalogued as COSV50747816; called by muse, mutect2
- AFF2 | c.2733A>C p.K911N | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53989454; called by muse, mutect2, varscan2
- AGBL1 | c.713A>G p.E238G | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); catalogued as COSV69799466; called by muse, mutect2, varscan2
- AHNAK2 | c.623A>G p.Q208R | Missense Mutation (SNP) | VAF 19/25 reads (76%) | SIFT deleterious (0.02); PolyPhen benign (0.221); catalogued as COSV60915377; called by muse, mutect2, varscan2
- AKAP12 | c.1864C>T p.R622C | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs143476871, COSV53583621; called by muse, mutect2, varscan2
- ANK2 | c.8224C>T p.H2742Y | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV52152540, COSV52161326; called by muse, mutect2, varscan2
- ARHGAP18 | c.115C>T p.R39C | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as rs202226965, COSV63764463; called by muse, mutect2, varscan2
- ARHGEF18 | c.335G>T p.G112V (on ENST00000359920 / NM_001130955.2; = p.G8V on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/38 reads (68%) | SIFT tolerated (0.18); PolyPhen benign (0.096); catalogued as COSV60469815, COSV60470365; called by muse, mutect2, varscan2
- ARMCX5-GPRASP2 | c.112G>C p.A38P | Missense Mutation (SNP) | VAF 22/121 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV63437912; called by muse, mutect2, varscan2
- ARPP21 | c.1005A>T p.R335S | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV51797802; called by muse, mutect2
- ASTN2 | c.1123C>T p.R375C | Missense Mutation (SNP) | VAF 27/45 reads (60%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.973); catalogued as rs371054320, COSV57777895; called by muse, mutect2, varscan2
- ATG4D | c.601C>T p.Q201* | Nonsense Mutation (SNP) | VAF 23/35 reads (66%) | catalogued as COSV58762642; called by muse, mutect2
- ATP5F1B | c.772T>G p.L258V | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.191); catalogued as COSV56260990; called by muse, mutect2, varscan2
- B3GAT1 | c.59T>C p.L20P | Missense Mutation (SNP) | VAF 10/198 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV56996978; called by muse, mutect2
- BCHE | c.1522C>A p.P508T | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1028387606, COSV52256875; called by muse, mutect2
- BRAT1 | c.2434T>A p.F812I | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV61395324; called by muse, mutect2, varscan2
- C2CD3 | c.2702T>G p.L901R | Missense Mutation (SNP) | VAF 250/311 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58089560; called by muse, mutect2, varscan2
- CAPN10 | c.969G>C p.E323D | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs1352000053, COSV54376627, COSV99550551; called by muse, mutect2, varscan2
- CCDC178 | c.2251G>C p.D751H (on ENST00000383096 / NM_001105528.3; = p.D713H on NM_198995.3) | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as COSV55772731; called by muse, varscan2
- CD1C | c.61+1G>C p.X21_splice | Splice Site (SNP) | VAF 9/91 reads (10%) | catalogued as COSV63806429, COSV63806447; called by muse, mutect2, varscan2
- CDC42BPB | c.1091C>T p.P364L | Missense Mutation (SNP) | VAF 27/47 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63474964; called by muse, mutect2, varscan2
- CDKL4 | c.577G>C p.E193Q | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV66509609; called by muse, mutect2, varscan2
- CEACAM1 | c.674G>T p.R225L | Missense Mutation (SNP) | VAF 64/239 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.178); catalogued as COSV50727316; called by muse, mutect2, varscan2
- CELA2B | c.175G>A p.G59R | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs202130301, COSV65545615; called by muse, mutect2
- CES1 | c.107A>C p.K36T | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.961); catalogued as COSV62085890; called by muse, mutect2
- CLCN6 | c.1457G>A p.S486N | Missense Mutation (SNP) | VAF 35/69 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV56740134; called by muse, mutect2, varscan2
- CLEC9A | c.207A>C p.Q69H | Missense Mutation (SNP) | VAF 14/233 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.049); catalogued as COSV63350325; called by muse, mutect2
- CNBD1 | c.1187T>G p.L396R | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV73072298, COSV73072404, COSV73073941; called by muse, mutect2, varscan2
- CNTNAP5 | c.2057G>A p.R686H | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs374739161; called by muse, mutect2, varscan2
- COL11A2 | c.2062G>A p.G688R (on ENST00000341947 / NM_080680.3; = p.G581R on NM_080679.2) | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs754930743, COSV59496916; called by muse, mutect2, varscan2
- COL12A1 | c.8581A>G p.S2861G | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.015); catalogued as COSV100486671, COSV59396037; called by muse, mutect2
- CPXM2 | c.445T>A p.F149I | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.78); catalogued as COSV53862051, COSV53862935; called by muse, mutect2, varscan2
- CSHL1 | c.472-1G>T p.X158_splice (on ENST00000309894 / NM_022581.3; = p.X64_splice on NM_001318.4) | Splice Site (SNP) | VAF 8/124 reads (6%) | catalogued as COSV99367720; called by muse, mutect2
- CSMD1 | c.949T>G p.L317V | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.867); catalogued as COSV101227511, COSV68173437; called by muse, mutect2, varscan2
- CSMD3 | c.9775T>A p.C3259S (on ENST00000297405 / NM_001363185.1; = p.C3090S on NM_052900.3) | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV52181223; called by muse, mutect2, varscan2
- CUBN | c.2098T>G p.L700V | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.071); catalogued as COSV64715709; called by muse, mutect2, varscan2
- DAAM2 | c.3145C>T p.R1049* (on ENST00000274867 / NM_001201427.2; = p.R1048* on NM_015345.3) | Nonsense Mutation (SNP) | VAF 21/71 reads (30%) | catalogued as rs759817118, COSV51317915; called by muse, mutect2, varscan2
- DCP1B | c.287A>G p.Q96R | Missense Mutation (SNP) | VAF 38/80 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54969001; called by muse, mutect2, varscan2
- DNAH1 | c.7377G>A p.E2459= | Splice Region (SNP) | VAF 74/132 reads (56%) | catalogued as COSV70227494, COSV70229045; called by muse, mutect2, varscan2
- DNAH17 | c.2765G>A p.R922H | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as rs534483320, COSV101101082; called by muse, mutect2
- DNAH5 | c.10260C>G p.N3420K | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54224761; called by muse, mutect2, varscan2
- DNAH7 | c.8977C>A p.P2993T | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1241532915, COSV56754782, COSV56762117, COSV56772823; called by muse, mutect2, varscan2
- DNAJA2 | c.1080A>C p.E360D | Missense Mutation (SNP) | VAF 43/282 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV57694762; called by muse, mutect2, varscan2
- DOK4 | c.893C>T p.S298L | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.096); catalogued as rs531274848, COSV54672656; called by muse, mutect2, varscan2
- EPB41L3 | c.1390T>G p.L464V | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.018); catalogued as COSV59453569, COSV59462802; called by muse, mutect2, varscan2
- EPHA3 | c.620A>T p.K207M | Missense Mutation (SNP) | VAF 79/221 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV60693190, COSV60703581, COSV60705777; called by muse, mutect2, varscan2
- EPHA6 | c.1391A>G p.K464R | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.992); catalogued as COSV67572128; called by muse, mutect2, varscan2
- EPHB1 | c.2577C>A p.D859E | Missense Mutation (SNP) | VAF 11/128 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.973); catalogued as COSV67661622; called by muse, mutect2
- ESRRG | c.805T>A p.C269S | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.999); catalogued as COSV63160859; called by muse, mutect2
- FAAH2 | c.1185C>G p.I395M | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT tolerated (0.27); PolyPhen benign (0.026); catalogued as COSV66507626; called by muse, mutect2, varscan2
- FAM237A | c.383C>T p.A128V | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as rs138933434, COSV101405558; called by muse, varscan2
- FAP | c.1369G>A p.D457N | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs780875561, COSV51861858; called by muse, mutect2, varscan2
- FGD5 | c.3829C>T p.R1277W | Missense Mutation (SNP) | VAF 38/76 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371834292; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as COSV63043875; called by muse, mutect2, varscan2
- FZD10 | c.929C>T p.T310M | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1453957716, COSV57473603; called by muse, mutect2, varscan2
- GJA8 | c.432G>C p.E144D | Missense Mutation (SNP) | VAF 53/180 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); catalogued as COSV53788910; called by muse, mutect2, varscan2
- GLUD2 | c.1580A>C p.K527T | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.094); catalogued as COSV60151950; called by muse, mutect2, varscan2
- GPR158 | c.1343G>A p.R448Q | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.937); catalogued as rs774310703, COSV66270308; called by muse, mutect2, varscan2
- GRID1 | c.443G>A p.R148H | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.947); catalogued as rs150264113; called by muse, mutect2, varscan2
- GYPC | c.128G>T p.G43V | Missense Mutation (SNP) | VAF 28/106 reads (26%) | SIFT tolerated, low confidence (0.54); PolyPhen probably damaging (0.979); catalogued as COSV52144768; called by muse, mutect2, varscan2
- HECW1 | c.1142G>A p.R381Q | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0); catalogued as rs375948910; called by muse, mutect2, varscan2
- HERC4 | c.2870A>C p.E957A (on ENST00000395198 / NM_022079.3; = p.E949A on NM_015601.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.45); PolyPhen benign (0.062); catalogued as COSV53271124, COSV99516819; called by muse, mutect2, varscan2
- IGDCC4 | c.1234G>C p.G412R | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV61536826; called by muse, mutect2
- IMPG2 | c.1602T>G p.S534R | Missense Mutation (SNP) | VAF 31/53 reads (58%) | SIFT deleterious (0.01); PolyPhen benign (0.299); catalogued as COSV51978243; called by muse, mutect2, varscan2
- KAT2B | c.625T>A p.S209T | Missense Mutation (SNP) | VAF 24/42 reads (57%) | SIFT tolerated (0.19); PolyPhen benign (0.369); catalogued as COSV55429363; called by muse, mutect2, varscan2
- KCNT2 | c.1783+2T>G p.X595_splice | Splice Site (SNP) | VAF 9/71 reads (13%) | catalogued as COSV54079640; called by muse, mutect2, varscan2
- KHDRBS2 | c.491A>G p.N164S | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.967); catalogued as COSV55453437; called by muse, mutect2, varscan2
- KIAA0753 | c.2224T>G p.L742V | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.655); catalogued as COSV63234730; called by muse, mutect2, varscan2
- LCE1F | c.13C>A p.Q5K | Missense Mutation (SNP) | VAF 15/115 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.018); catalogued as COSV57669292; called by muse, mutect2, varscan2
- LGI4 | c.1354G>A p.G452S | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755198882, COSV59533557, COSV59533573; called by muse, mutect2, varscan2
- LIG1 | c.362G>A p.R121H | Missense Mutation (SNP) | VAF 25/160 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs377155700; called by muse, mutect2, varscan2
- LIMCH1 | c.3110T>A p.I1037N | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58283768, COSV58297018; called by muse, mutect2, varscan2
- LRP1B | c.9902C>A p.P3301H | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67220146; called by muse, mutect2, varscan2
- LRP1B | c.5081A>C p.K1694T | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.722); catalogued as COSV67220150; called by muse, mutect2, varscan2
- LRPPRC | c.2297-1G>A p.X766_splice | Splice Site (SNP) | VAF 3/27 reads (11%) | catalogued as COSV53238327; called by muse, mutect2
- MAP1B | c.3502T>A p.S1168T | Missense Mutation (SNP) | VAF 16/26 reads (62%) | SIFT tolerated (0.27); PolyPhen benign (0.024); catalogued as COSV57099032; called by muse, mutect2, varscan2
- MAP3K12 | c.1828T>C p.S610P | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); catalogued as COSV57232834; called by muse, mutect2, varscan2
- MARCHF6 | c.86C>T p.T29I | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as COSV56881443, COSV56886992; called by muse, mutect2, varscan2
- MBD5 | c.4408G>T p.G1470W | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV68697000; called by muse, mutect2
- MDGA2 | c.1885A>C p.S629R (on ENST00000399232 / NM_001113498.2; = p.S331R on NM_182830.4) | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.033); catalogued as COSV62080924; called by muse, mutect2, varscan2
- MECOM | c.2768A>T p.E923V (on ENST00000468789 / NM_001105078.4; = p.E1111V on NM_004991.4) | Missense Mutation (SNP) | VAF 16/198 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.15); catalogued as COSV99243718; called by muse, mutect2
- MECOM | c.2767G>T p.E923* (on ENST00000468789 / NM_001105078.4; = p.E1111* on NM_004991.4) | Nonsense Mutation (SNP) | VAF 16/198 reads (8%) | catalogued as COSV99243719, COSV99245217; called by muse, mutect2
- MED30 | c.379G>A p.D127N | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.021); catalogued as COSV52067220; called by muse, mutect2
- MINAR1 | c.1984C>T p.R662W | Missense Mutation (SNP) | VAF 44/188 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.446); catalogued as rs147214893; called by muse, mutect2, varscan2
- MYC | c.568G>C p.D190H (on ENST00000377970; = p.D205H on NM_002467.6) | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52372757; called by muse, mutect2
- NAA30 | c.747C>A p.H249Q | Missense Mutation (SNP) | VAF 41/238 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.053); catalogued as COSV53648615; called by muse, mutect2, varscan2
- NBN | c.252G>T p.Q84H | Missense Mutation (SNP) | VAF 64/101 reads (63%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.968); catalogued as COSV55373045; called by muse, mutect2, varscan2
- NBPF11 | c.518A>T p.D173V | Missense Mutation (SNP) | VAF 30/377 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs1290073759; called by muse, mutect2
- NEXMIF | c.4379A>G p.E1460G | Missense Mutation (SNP) | VAF 34/63 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50021655, COSV50051299; called by muse, mutect2, varscan2
- NRXN1 | c.1847G>T p.G616V | Missense Mutation (SNP) | VAF 66/122 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58452704; called by muse, mutect2, varscan2
- NUP205 | c.4463G>A p.G1488D | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53659193; called by muse, mutect2, varscan2
- NYNRIN | c.2194G>C p.A732P | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); catalogued as rs376464969, COSV66842452; called by muse, mutect2, varscan2
- OR10S1 | c.532T>C p.F178L | Missense Mutation (SNP) | VAF 17/118 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.1); catalogued as COSV73342792; called by muse, mutect2, varscan2
- OR11H4 | c.786T>G p.Y262* | Nonsense Mutation (SNP) | VAF 83/221 reads (38%) | catalogued as COSV59560243; called by muse, mutect2, varscan2
- OR11L1 | c.946A>G p.S316G | Missense Mutation (SNP) | VAF 8/101 reads (8%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV63314495; called by muse, mutect2
- OR2AK2 | c.70A>T p.N24Y | Missense Mutation (SNP) | VAF 20/168 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.851); catalogued as COSV63552775; called by muse, mutect2, varscan2
- OR2M5 | c.691G>T p.G231* | Nonsense Mutation (SNP) | VAF 50/426 reads (12%) | catalogued as COSV63546261; called by muse, mutect2, varscan2
- OR2T1 | c.658A>T p.I220F | Missense Mutation (SNP) | VAF 44/126 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV63541899; called by muse, mutect2, varscan2
- OR4C11 | c.619A>C p.S207R | Missense Mutation (SNP) | VAF 50/78 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as COSV56353063, COSV56353716; called by muse, mutect2, varscan2
- OR4D5 | c.481G>T p.A161S | Missense Mutation (SNP) | VAF 21/150 reads (14%) | SIFT tolerated (0.68); PolyPhen benign (0.007); catalogued as COSV58306904; called by muse, mutect2, varscan2
- OR52N1 | c.133T>G p.F45V | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT tolerated (0.49); PolyPhen benign (0.028); catalogued as COSV57692824; called by muse, mutect2, varscan2
- ORC6 | c.428C>T p.A143V | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as COSV99530757; called by mutect2, varscan2
- P2RY13 | c.131A>G p.Q44R | Missense Mutation (SNP) | VAF 23/212 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.266); catalogued as COSV56378908; called by muse, mutect2, varscan2
- PADI2 | c.1976A>C p.K659T | Missense Mutation (SNP) | VAF 54/142 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.674); catalogued as COSV64953804; called by muse, mutect2, varscan2
- PADI2 | c.274A>C p.K92Q | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1329947298, COSV64945859; called by muse, mutect2, varscan2
- PARP8 | c.1912C>T p.H638Y | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.885); catalogued as COSV55860053; called by muse, mutect2, varscan2
- PCDH15 | c.3143T>G p.L1048R | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.83); catalogued as COSV57311440, COSV57346173; called by muse, mutect2, varscan2
- PCDH18 | c.3204C>A p.N1068K | Missense Mutation (SNP) | VAF 29/45 reads (64%) | SIFT tolerated (0.79); PolyPhen benign (0.007); catalogued as COSV61268385; called by muse, mutect2, varscan2
- PCDHGA12 | c.1888C>T p.R630* | Nonsense Mutation (SNP) | VAF 103/133 reads (77%) | catalogued as COSV52752093; called by muse, mutect2, varscan2
- PDHA2 | c.467A>C p.K156T | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.649); catalogued as COSV54779196; called by muse, mutect2, varscan2
- PENK | c.283T>A p.L95M | Missense Mutation (SNP) | VAF 40/147 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.049); catalogued as COSV59241316; called by muse, mutect2, varscan2
- PLEKHA4 | c.312C>A p.Y104* | Nonsense Mutation (SNP) | VAF 43/88 reads (49%) | catalogued as COSV54362872, COSV54363092; called by muse, mutect2, varscan2
- POLR3A | c.1310G>A p.R437Q | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV64931036; called by muse, mutect2, varscan2
- PRAMEF18 | c.437C>A p.P146H | Missense Mutation (SNP) | VAF 120/488 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1330024277; called by muse, mutect2, varscan2
- RASA4 | c.421G>C p.E141Q | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.979); catalogued as COSV99499732; called by muse, mutect2, varscan2
- RB1 | c.2363G>A p.S788N | Missense Mutation (SNP) | VAF 53/149 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV57307336; called by muse, mutect2, varscan2
- RET | c.2116G>A p.V706M | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.448); catalogued as rs137855422, COSV60694204; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RPL28 | c.141G>C p.K47N | Missense Mutation (SNP) | VAF 6/150 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV59804837; called by muse, mutect2
- RREB1 | c.2270T>C p.L757P | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as COSV58558069; called by muse, mutect2, varscan2
- SAMHD1 | c.1717A>G p.T573A (on ENST00000262878 / NM_001363729.2; = p.T608A on NM_015474.4) | Missense Mutation (SNP) | VAF 69/181 reads (38%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1174257327, COSV53429654; called by muse, mutect2, varscan2
- SCN2A | c.1892C>T p.A631V | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.013); catalogued as rs1442188692, COSV51841132; called by muse, mutect2, varscan2
- SEPTIN3 | c.885T>A p.C295* | Nonsense Mutation (SNP) | VAF 6/38 reads (16%) | catalogued as COSV52172195, COSV99352035; called by muse, mutect2, varscan2
- SETX | c.5213A>C p.H1738P | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.043); catalogued as COSV56385173; called by muse, mutect2, varscan2
- SHC1 | c.1366C>T p.R456W (on ENST00000368445 / NM_183001.5; = p.R347W on NM_003029.5) | Missense Mutation (SNP) | VAF 54/213 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as rs747330503, COSV63534682; called by muse, mutect2, varscan2
- SHROOM2 | c.1358A>G p.Q453R | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.439); catalogued as COSV66606600; called by muse, mutect2
- SHROOM3 | c.2689G>A p.E897K | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.066); catalogued as COSV56023036; called by muse, mutect2
- SLC15A4 | c.1000G>A p.V334M | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs766215824, COSV57161514; called by muse, mutect2, varscan2
- SOX3 | c.497A>C p.N166T | Missense Mutation (SNP) | VAF 37/74 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65168215; called by muse, mutect2, varscan2
- SPX | c.16A>C p.S6R | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as COSV57020762, COSV99919500; called by muse, mutect2, varscan2
- STK32B | c.1086C>A p.F362L | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51487335; called by muse, mutect2, varscan2
- TAOK2 | c.1213G>C p.G405R | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.963); catalogued as COSV54235757; called by muse, varscan2
- TBC1D16 | c.1514A>T p.E505V | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); catalogued as COSV60476959, COSV60477720; called by muse, mutect2, varscan2
- TENM1 | c.4743C>A p.S1581R | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.051); catalogued as COSV64431849; called by muse, mutect2, varscan2
- TFAP2C | c.1072C>A p.L358M | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.035); catalogued as COSV52371462; called by muse, mutect2, varscan2
- THYN1 | c.654C>A p.S218R | Missense Mutation (SNP) | VAF 139/177 reads (79%) | SIFT tolerated (0.05); PolyPhen benign (0.057); catalogued as COSV55545086; called by muse, mutect2, varscan2
- TLR8 | c.322G>A p.G108S (on ENST00000218032 / NM_138636.5; = p.G126S on NM_016610.4) | Missense Mutation (SNP) | VAF 18/149 reads (12%) | SIFT tolerated (0.77); PolyPhen benign (0.003); catalogued as rs1281012171, COSV54317935; called by muse, mutect2
- TMOD4 | c.572G>A p.R191Q | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs746686213, COSV54859746; called by muse, mutect2, varscan2
- TNFRSF19 | c.1130G>T p.R377I | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.461); catalogued as COSV50313612; called by muse, mutect2, varscan2
- TPO | c.1345A>T p.T449S | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.978); catalogued as COSV61097046, COSV61101932; called by muse, mutect2, varscan2
- TRAK1 | c.2834A>C p.K945T | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.38); catalogued as COSV59642629; called by muse, mutect2, varscan2
- TRIM13 | c.107G>C p.G36A | Missense Mutation (SNP) | VAF 37/67 reads (55%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.807); catalogued as COSV53949505; called by muse, mutect2, varscan2
- TRIM63 | c.635A>C p.K212T | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.062); catalogued as COSV65328441; called by muse, mutect2, varscan2
- TRIML2 | c.230T>G p.L77R | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.745); catalogued as COSV58716133; called by muse, mutect2, varscan2
- TRO | c.434T>C p.V145A | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.007); catalogued as COSV51501524; called by muse, mutect2
- TRPC1 | c.2221C>T p.R741C (on ENST00000476941 / NM_001251845.2; = p.R707C on NM_003304.4) | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs538677775, COSV56425259; called by muse, mutect2, varscan2
- TRRAP | c.7718C>T p.T2573M (on ENST00000359863 / NM_001244580.1; = p.T2555M on NM_003496.3) | Missense Mutation (SNP) | VAF 38/344 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.058); catalogued as rs76587346, COSV62839015; called by muse, mutect2, varscan2
- TTN | c.88172C>A p.S29391Y (on ENST00000591111; = p.S21967Y on NM_003319.4) | Missense Mutation (SNP) | VAF 88/295 reads (30%) | PolyPhen probably damaging (0.914); catalogued as COSV60061623; called by muse, mutect2, varscan2
- TTN | c.49781G>A p.R16594H (on ENST00000591111; = p.R9170H on NM_003319.4) | Missense Mutation (SNP) | VAF 100/255 reads (39%) | PolyPhen benign (0.165); catalogued as rs750125113, COSV60061676; called by muse, mutect2, varscan2
- U2SURP | c.2626G>C p.E876Q | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.46); catalogued as COSV67530930; called by muse, mutect2, varscan2
- UGT2B10 | c.1537T>A p.F513I | Missense Mutation (SNP) | VAF 51/94 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.333); catalogued as COSV55320312; called by muse, mutect2, varscan2
- VSIG4 | c.596A>C p.K199T | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.761); catalogued as COSV66073743; called by muse, mutect2, varscan2
- WDR44 | c.2423A>C p.K808T | Missense Mutation (SNP) | VAF 24/672 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as COSV54163516, COSV54165432; called by muse, mutect2
- ZBTB1 | c.1241T>G p.V414G | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as COSV62438165; called by muse, mutect2, varscan2
- ZBTB40 | c.2112G>T p.Q704H | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV65145312; called by muse, mutect2, varscan2
- ZDHHC11 | c.1196C>G p.T399R | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0); catalogued as COSV99362083; called by muse, varscan2
- ZFHX3 | c.25G>A p.V9I | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs200637584, COSV51718798; called by muse, mutect2, varscan2
- ZFHX4 | c.8693G>A p.R2898H | Missense Mutation (SNP) | VAF 35/61 reads (57%) | SIFT tolerated (0.43); PolyPhen benign (0.315); catalogued as rs755881840, COSV50495239; called by muse, mutect2, varscan2
- ZNF2 | c.1178A>G p.Q393R (on ENST00000611147 / NM_001291605.2; = p.Q380R on NM_021088.4) | Missense Mutation (SNP) | VAF 24/169 reads (14%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.827); catalogued as rs767508454, COSV54636979; called by muse, mutect2, varscan2
- ZNF215 | c.1283T>G p.L428R | Missense Mutation (SNP) | VAF 37/50 reads (74%) | SIFT deleterious (0.01); PolyPhen benign (0.154); catalogued as COSV53493053; called by muse, mutect2, varscan2
- ZNF385D | c.1054A>T p.S352C | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.095); catalogued as COSV55755863; called by muse, mutect2, varscan2
- ZNF473 | c.1850G>A p.R617K | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV54523166; called by muse, mutect2, varscan2
- ZNF536 | c.1142G>A p.R381H | Missense Mutation (SNP) | VAF 53/170 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV62824260; called by muse, mutect2, varscan2
- ZNF804A | c.3548C>A p.A1183D | Missense Mutation (SNP) | VAF 74/232 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV56448778; called by muse, mutect2, varscan2
- CCL20 | c.253_254del p.I85Cfs*6 | Frame Shift Del (DEL) | VAF 22/74 reads (30%) | called by pindel, varscan2
- CNTROB | c.2218_2221del p.T740Sfs*24 | Frame Shift Del (DEL) | VAF 17/123 reads (14%) | called by mutect2, pindel, varscan2
- FAAP20 | c.215del p.P72Rfs*87 | Frame Shift Del (DEL) | VAF 12/104 reads (12%) | called by mutect2, pindel, varscan2
- GTF2IRD2 | c.2639C>T p.T880M | Missense Mutation (SNP) | VAF 30/39 reads (77%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.804); called by mutect2, varscan2
- ANO4 | c.1212T>C p.C404= (on ENST00000392977 / NM_001286615.2; = p.C369= on NM_178826.4) | Silent (SNP) | VAF 23/52 reads (44%) | catalogued as COSV54595956; called by muse, mutect2, varscan2
- ARHGAP20 | c.3450T>G p.S1150= | Silent (SNP) | VAF 19/145 reads (13%) | catalogued as COSV52811258; called by muse, mutect2, varscan2
- ASPM | c.2835C>A p.G945= | Silent (SNP) | VAF 13/91 reads (14%) | catalogued as COSV54129884; called by muse, mutect2, varscan2
- ATP10A | c.4062T>C p.S1354= | Silent (SNP) | VAF 43/102 reads (42%) | catalogued as rs1421036038, COSV100791009, COSV63517382; called by muse, mutect2, varscan2
- AURKA | c.747G>A p.S249= | Silent (SNP) | VAF 27/108 reads (25%) | catalogued as rs1438638050, COSV57168479; called by muse, mutect2, varscan2
- CLEC2B | c.435G>A p.R145= | Silent (SNP) | VAF 102/358 reads (28%) | catalogued as COSV57309603; called by muse, mutect2, varscan2
- CUBN | c.8697T>C p.T2899= | Silent (SNP) | VAF 17/85 reads (20%) | catalogued as rs1429799817, COSV64715705; called by muse, mutect2, varscan2
- CUX1 | c.1281G>A p.P427= | Silent (SNP) | VAF 16/167 reads (10%) | catalogued as rs782186138, COSV52899692, COSV52909700; called by muse, mutect2
- DCAF4L2 | c.1110T>C p.S370= | Silent (SNP) | VAF 10/102 reads (10%) | catalogued as COSV100150371; called by muse, mutect2
- DNASE1L3 | c.678G>A p.K226= | Silent (SNP) | VAF 15/67 reads (22%) | catalogued as COSV59155942; called by muse, mutect2, varscan2
- DSEL | c.1458T>G p.T486= | Silent (SNP) | VAF 13/29 reads (45%) | catalogued as COSV59491524, COSV59492166; called by muse, mutect2, varscan2
- DUOXA2 | c.549G>A p.T183= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as COSV50993562; called by muse, mutect2, varscan2
- EHMT2 | c.1896G>A p.L632= | Silent (SNP) | VAF 25/215 reads (12%) | catalogued as COSV64996011; called by muse, mutect2, varscan2
- ERRFI1 | c.981G>A p.P327= | Silent (SNP) | VAF 87/256 reads (34%) | catalogued as rs766752153, COSV66310655; called by muse, mutect2, varscan2
- FAM124B | c.366G>A p.Q122= | Silent (SNP) | VAF 19/50 reads (38%) | catalogued as COSV66272055; called by muse, mutect2, varscan2
- FAM234A | c.195C>T p.V65= | Silent (SNP) | VAF 95/250 reads (38%) | catalogued as rs754664273, COSV56994408; called by muse, mutect2, varscan2
- FRG2C | c.324A>G p.Q108= | Silent (SNP) | VAF 12/102 reads (12%) | called by muse, varscan2
- GABRG1 | c.984T>G p.S328= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as COSV54954145; called by muse, mutect2, varscan2
- GEMIN4 | c.1659C>T p.V553= | Silent (SNP) | VAF 8/55 reads (15%) | catalogued as COSV56745903; called by muse, mutect2, varscan2
- IGF2BP2 | c.903A>G p.E301= | Silent (SNP) | VAF 22/171 reads (13%) | catalogued as COSV60486033; called by muse, mutect2, varscan2
- KIF5A | c.2511G>A p.L837= | Silent (SNP) | VAF 152/960 reads (16%) | catalogued as COSV54054508; called by muse, mutect2, varscan2
- KLHL13 | c.192A>C p.G64= | Silent (SNP) | VAF 15/56 reads (27%) | catalogued as COSV53247585; called by muse, mutect2, varscan2
- KRT27 | c.321G>A p.E107= | Silent (SNP) | VAF 91/121 reads (75%) | catalogued as rs778812184, COSV56971817; called by muse, mutect2, varscan2
- LRP1B | c.1710C>T p.I570= | Silent (SNP) | VAF 32/168 reads (19%) | catalogued as COSV67220155; called by muse, mutect2, varscan2
- LYZL2 | c.291G>A p.A97= (on ENST00000375318; = p.A51= on NM_183058.3) | Silent (SNP) | VAF 27/86 reads (31%) | catalogued as rs1133364; called by muse, mutect2, varscan2
- MBNL1 | c.87G>A p.R29= | Silent (SNP) | VAF 29/138 reads (21%) | catalogued as rs773981630, COSV56828041; called by muse, mutect2, varscan2
- MYH8 | c.1221C>T p.V407= | Silent (SNP) | VAF 89/236 reads (38%) | catalogued as COSV67965084; called by muse, mutect2, varscan2
- NCKAP5 | c.4857G>A p.T1619= | Silent (SNP) | VAF 35/82 reads (43%) | catalogued as rs367995102, COSV100494298; called by muse, mutect2, varscan2
- NCKAP5 | c.2446C>T p.L816= | Silent (SNP) | VAF 36/246 reads (15%) | catalogued as COSV58443969; called by muse, mutect2, varscan2
- NID1 | c.1572C>T p.F524= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as rs1024805205; called by muse, mutect2
- PCDHB4 | c.1551G>A p.S517= | Silent (SNP) | VAF 85/217 reads (39%) | catalogued as rs782072958, COSV52022371, COSV52022408; called by muse, mutect2, varscan2
- PCDHB8 | c.1956G>A p.P652= | Silent (SNP) | VAF 71/105 reads (68%) | catalogued as rs782285661, COSV50767905; called by muse, mutect2, varscan2
- PCLO | c.2307A>T p.S769= | Silent (SNP) | VAF 15/192 reads (8%) | catalogued as COSV61635255; called by muse, mutect2
- RBL1 | c.1915T>C p.L639= | Silent (SNP) | VAF 4/42 reads (10%) | catalogued as rs1209270093, COSV60329953; called by muse, mutect2
- RBM25 | c.1713G>A p.R571= | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as COSV56200029; called by muse, mutect2, varscan2
- RDH16 | c.183G>A p.L61= | Silent (SNP) | VAF 198/418 reads (47%) | catalogued as COSV62458134; called by muse, mutect2, varscan2
- RIMS2 | c.1269T>C p.S423= (on ENST00000666250 / NM_001348490.2; = p.S231= on NM_014677.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 11/54 reads (20%) | catalogued as rs778061023, COSV51651026, COSV51655287, COSV51702036; called by muse, mutect2, varscan2
- RTN3 | c.1902T>C p.Y634= (on ENST00000377819 / NM_001265589.2; = p.Y615= on NM_201428.3) | Silent (SNP) | VAF 33/66 reads (50%) | catalogued as COSV58028753; called by muse, mutect2, varscan2
- SERPINA12 | c.102C>T p.S34= | Silent (SNP) | VAF 61/98 reads (62%) | catalogued as rs201642706, COSV57943650; called by muse, mutect2, varscan2
- SERPINB3 | c.954C>T p.T318= | Silent (SNP) | VAF 16/93 reads (17%) | catalogued as rs753692328, COSV52191655; called by muse, mutect2, varscan2
- SLIT2 | c.903C>A p.T301= | Silent (SNP) | VAF 22/72 reads (31%) | catalogued as COSV56572589; called by muse, mutect2, varscan2
- SPATA33 | c.345G>A p.P115= | Silent (SNP) | VAF 23/89 reads (26%) | catalogued as rs766642860, COSV56377536; called by muse, mutect2, varscan2
- SPEG | c.6825C>T p.H2275= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as rs753319664, COSV56668824; called by muse, mutect2, varscan2
- TECRL | c.24C>T p.L8= | Silent (SNP) | VAF 27/46 reads (59%) | catalogued as rs1226729532, COSV67085470, COSV67087056; called by muse, mutect2, varscan2
- TNNI1 | c.363C>T p.D121= | Silent (SNP) | VAF 11/59 reads (19%) | catalogued as rs201627016; called by muse, mutect2, varscan2
- TRPC4 | c.1869T>A p.S623= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as COSV59000049; called by muse, mutect2, varscan2
- TSFM | c.352T>C p.L118= | Silent (SNP) | VAF 5/96 reads (5%) | catalogued as COSV55744170; called by muse, mutect2
- UGT3A1 | c.847T>C p.L283= | Silent (SNP) | VAF 29/65 reads (45%) | catalogued as COSV57098129; called by muse, mutect2, varscan2
- USH2A | c.4851T>C p.A1617= | Silent (SNP) | VAF 13/93 reads (14%) | catalogued as COSV100229471, COSV56338916, COSV56351150, COSV56369282; called by muse, mutect2, varscan2
- VWA3B | c.1284G>A p.P428= | Silent (SNP) | VAF 10/69 reads (14%) | catalogued as rs372193532; called by muse, mutect2, varscan2
- XK | c.1041C>T p.C347= | Silent (SNP) | VAF 21/116 reads (18%) | catalogued as rs368546529, COSV66120140; called by muse, mutect2, varscan2
- XKR7 | c.1278G>A p.A426= | Silent (SNP) | VAF 56/162 reads (35%) | catalogued as COSV73813071; called by muse, mutect2, varscan2
- ZNF142 | c.2502A>C p.S834= (on ENST00000411696 / NM_001379660.1; = p.S634= on NM_001105537.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 25/55 reads (45%) | catalogued as COSV68743726; called by muse, mutect2, varscan2
- ZRANB3 | c.76C>T p.L26= | Silent (SNP) | VAF 11/42 reads (26%) | catalogued as COSV51502003; called by muse, mutect2, varscan2
- ZXDA | c.285G>A p.P95= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as rs752616506, COSV100699516, COSV62387482; called by muse, mutect2, varscan2
- AK9 | c.3633+13_3633+15del | Intron (DEL) | VAF 4/26 reads (15%) | catalogued as rs201441562; called by pindel, varscan2
- PDZRN4 | c.844-68481A>T | Intron (SNP) | VAF 51/155 reads (33%) | catalogued as COSV100113304; called by muse, mutect2, varscan2
- PLEKHA8P1 | n.1123T>G | RNA (SNP) | VAF 64/161 reads (40%) | called by muse, mutect2, varscan2
- SNORD115-40 | n.81C>G | RNA (SNP) | VAF 102/223 reads (46%) | called by muse, mutect2, varscan2
- SNORD116-27 | n.87A>C | RNA (SNP) | VAF 22/28 reads (79%) | called by muse, mutect2, varscan2
- SYTL2 | c.1615+1298G>A | Intron (SNP) | VAF 12/82 reads (15%) | catalogued as rs376203930; called by muse, mutect2, varscan2
- XIST | n.8646T>G | RNA (SNP) | VAF 22/84 reads (26%) | called by muse, mutect2, varscan2
